Somatic mutation profile of tumor specimen TCGA-CC-A1HT-01A (aliquot TCGA-CC-A1HT-01A-11D-A12Z-10) from TCGA case TCGA-CC-A1HT, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 50.8 years (18,553 days).
Specimen TCGA-CC-A1HT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ded480a-8287-4460-9987-24c09b91a2bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A1HT-10A (Blood Derived Normal), aliquot TCGA-CC-A1HT-10A-01D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48d0518d-2e48-4a08-8f51-f1a5fa375a3b

The open-access MAF lists 103 somatic variants for this specimen: 76 protein-altering or splice-affecting, 20 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 20, Frame Shift Del 4, Splice Site 4, Nonsense Mutation 4, Splice Region 3, Intron 3, 3'UTR 3, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRT14 | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs61027685, CM044653, CM055346, CM070974, COSV51420170; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 8/45 reads (18%) | hotspot (GDC flag); catalogued as rs868137297, CS1313555, COSV52688618, COSV52749979, COSV52994579, COSV52996344; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB1 | c.466A>T p.M156L | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs756530200, COSV55944714; called by muse, mutect2, varscan2
- ARHGEF18 | c.130T>A p.S44T | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV60466877; called by muse, mutect2, varscan2
- ATG14 | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 78/362 reads (22%) | catalogued as COSV55955465, COSV55958773; called by muse, mutect2, varscan2
- BTBD18 | c.1139C>A p.T380N | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV53553196; called by muse, mutect2
- CAPN15 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54834111; called by muse, mutect2, varscan2
- CDR2L | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs529209429, COSV61500604; called by muse, mutect2, varscan2
- CLTCL1 | c.856G>C p.D286H | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs191439705, COSV54224674, COSV54233964; called by muse, mutect2, varscan2
- CNTD1 | c.838C>A p.Q280K | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as COSV59311613; called by muse, mutect2, varscan2
- COBLL1 | c.2550A>T p.K850N (on ENST00000392717; = p.K812N on NM_014900.5) | Missense Mutation (SNP) | VAF 56/304 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as COSV52062838; called by muse, mutect2, varscan2
- CP | c.1170A>G p.I390M | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs201036476, COSV52828942; called by muse, mutect2, varscan2
- CSNK1E | c.546C>G p.I182M | Missense Mutation (SNP) | VAF 74/274 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.987); catalogued as COSV63290341; called by muse, mutect2, varscan2
- DACH1 | c.989C>A p.A330D | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.726); catalogued as COSV57488642; called by muse, mutect2, varscan2
- DDX31 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs367667543; called by muse, mutect2
- DNAH8 | c.2682+1G>T p.X894_splice | Splice Site (SNP) | VAF 19/139 reads (14%) | catalogued as COSV59423290; called by muse, mutect2, varscan2
- DOCK2 | c.4336C>T p.R1446W | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs750405913, COSV56940511; called by muse, mutect2
- EIF4G1 | c.3808G>A p.A1270T (on ENST00000346169 / NM_198241.3; = p.A1075T on NM_004953.5) | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as COSV59988904; called by muse, mutect2, varscan2
- ENPP6 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs139781867; called by muse, mutect2, varscan2
- EPC1 | c.344A>G p.Y115C | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53922962; called by muse, mutect2, varscan2
- FAM111B | c.1640T>G p.I547S | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV59110977; called by muse, mutect2, varscan2
- FAT3 | c.553G>T p.A185S | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53073439, COSV53073692; called by muse, mutect2, varscan2
- FLT1 | c.3636-1G>C p.X1212_splice | Splice Site (SNP) | VAF 7/60 reads (12%) | catalogued as COSV56717172; called by muse, mutect2, varscan2
- FNBP4 | c.2603C>A p.A868E | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); catalogued as COSV55445766; called by muse, mutect2, varscan2
- FRAS1 | c.4231C>T p.Q1411* | Nonsense Mutation (SNP) | VAF 26/189 reads (14%) | catalogued as COSV53587572; called by muse, mutect2, varscan2
- FRAS1 | c.11036C>T p.P3679L | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779623280, COSV53587608; called by muse, mutect2, varscan2
- GABRQ | c.1199C>A p.P400H | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.904); catalogued as COSV64780772; called by muse, mutect2, varscan2
- HMCN1 | c.4337T>A p.I1446N | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54875140; called by muse, mutect2, varscan2
- HYDIN | c.12454G>A p.D4152N | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.167); catalogued as COSV66636846, COSV66638877; called by muse, mutect2, varscan2
- IL9R | c.1159C>A p.L387M | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.775); catalogued as COSV54898099; called by muse, mutect2, varscan2
- INTS1 | c.4768G>A p.E1590K | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs781720568, COSV67176283; called by muse, mutect2, varscan2
- LRP1B | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV67184445, COSV67241706; called by muse, mutect2, varscan2
- MAGEC3 | c.1577A>G p.E526G | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.218); catalogued as COSV53575889; called by muse, mutect2, varscan2
- MME | c.2076+1G>T p.X692_splice | Splice Site (SNP) | VAF 120/753 reads (16%) | catalogued as COSV64705915; called by muse, mutect2, varscan2
- MPP1 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.465); catalogued as COSV65727952; called by muse, mutect2, varscan2
- MSH4 | c.2582C>T p.A861V | Missense Mutation (SNP) | VAF 40/750 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54196091; called by muse, mutect2
- MUC16 | c.37111A>T p.T12371S | Missense Mutation (SNP) | VAF 20/241 reads (8%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.071); catalogued as COSV67443131; called by muse, mutect2
- MUC16 | c.33308C>A p.T11103N | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.918); catalogued as COSV67443137; called by muse, mutect2, varscan2
- MUC16 | c.33307A>C p.T11103P | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.246); catalogued as COSV67443144; called by muse, mutect2, varscan2
- MUC7 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV59216987, COSV59219305; called by muse, mutect2, varscan2
- MYBL1 | c.1072T>C p.F358L | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV72918701; called by muse, mutect2
- MYRF | c.674C>T p.P225L (on ENST00000278836 / NM_001127392.3; = p.P216L on NM_013279.4) | Missense Mutation (SNP) | VAF 37/318 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs961109026, COSV53885604; called by muse, mutect2, varscan2
- MYT1L | c.3127G>A p.G1043R | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs774591482, COSV67701199; called by muse, mutect2, varscan2
- NF2 | c.1279G>T p.E427* | Nonsense Mutation (SNP) | VAF 25/97 reads (26%) | catalogued as CM002818, COSV58519935; called by muse, mutect2, varscan2
- NUP205 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs961820512, COSV53654643, COSV53665939; called by muse, mutect2, varscan2
- OR2W3 | c.810G>T p.Q270H | Missense Mutation (SNP) | VAF 72/264 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV64455997; called by muse, mutect2, varscan2
- OR5D13 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV62332649; called by muse, mutect2, varscan2
- PCDHB1 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60629389; called by muse, mutect2, varscan2
- PDE1C | c.1061C>T p.T354I | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV58502808; called by muse, mutect2, varscan2
- PIK3CB | c.1478T>C p.V493A | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV56683150; called by muse, mutect2, varscan2
- RELT | c.626-3C>T | Splice Region (SNP) | VAF 10/128 reads (8%) | catalogued as COSV99292742; called by muse, mutect2
- RPS15 | c.4-3C>T | Splice Region (SNP) | VAF 17/97 reads (18%) | catalogued as rs1307008927, COSV99245084; called by muse, mutect2, varscan2
- SEMA6C | c.1219C>A p.P407T | Missense Mutation (SNP) | VAF 151/403 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58999788; called by muse, mutect2, varscan2
- SGK3 | c.752A>G p.H251R | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61893475; called by muse, mutect2, varscan2
- SLC13A1 | c.734C>G p.A245G | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV52007878, COSV52009109; called by muse, mutect2, varscan2
- SPANXN3 | c.252G>T p.E84D | Missense Mutation (SNP) | VAF 15/253 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.343); catalogued as COSV65140900; called by muse, mutect2
- SPTA1 | c.3079C>A p.P1027T | Missense Mutation (SNP) | VAF 86/209 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100935508, COSV63748584; called by muse, mutect2, varscan2
- SYNE1 | c.10935C>A p.H3645Q (on ENST00000367255 / NM_182961.4; = p.H3630Q on NM_033071.3) | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV54901187; called by muse, mutect2, varscan2
- TACR3 | c.416C>A p.T139K | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59197710; called by muse, mutect2, varscan2
- TCAIM | c.1349T>G p.V450G | Missense Mutation (SNP) | VAF 53/345 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV61239893; called by muse, mutect2, varscan2
- TMBIM6 | c.418T>C p.Y140H | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.114); catalogued as COSV57278421; called by muse, mutect2, varscan2
- TMEM115 | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.674); catalogued as COSV51704250; called by muse, mutect2, varscan2
- TNP1 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.06); catalogued as COSV52696365, COSV52696642; called by muse, mutect2, varscan2
- TP53BP1 | c.1682C>G p.P561R | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV55495985; called by muse, mutect2, varscan2
- TRIM28 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV53398752; called by muse, mutect2, varscan2
- TRIM42 | c.342C>A p.S114= | Splice Region (SNP) | VAF 16/109 reads (15%) | catalogued as COSV53880089; called by muse, mutect2, varscan2
- TTN | c.101417C>G p.P33806R (on ENST00000591111; = p.P26382R on NM_003319.4) | Missense Mutation (SNP) | VAF 20/125 reads (16%) | PolyPhen possibly damaging (0.829); catalogued as COSV59875109; called by muse, mutect2, varscan2
- ZDBF2 | c.1661del p.P554Qfs*39 | Frame Shift Del (DEL) | VAF 11/83 reads (13%) | catalogued as COSV65630647; called by mutect2, pindel, varscan2
- ZNF253 | c.409A>T p.T137S | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.175); catalogued as COSV63036308; called by muse, mutect2, varscan2
- AXIN2 | c.829_830del p.S277Rfs*4 | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | called by mutect2, pindel
- DENND5B | c.1411dup p.M471Nfs*9 | Frame Shift Ins (INS) | VAF 39/228 reads (17%) | called by mutect2, pindel, varscan2
- LGALS9B | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 151/834 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.408); called by muse, varscan2
- NR2F2 | c.273_274del p.Y91* | Nonsense Mutation (DEL) | VAF 12/87 reads (14%) | called by mutect2, pindel, varscan2
- TYW1B | c.1363del p.E455Kfs*23 | Frame Shift Del (DEL) | VAF 86/426 reads (20%) | called by mutect2, varscan2
- VGLL4 | c.322_323del p.A108Cfs*98 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | called by pindel, varscan2
- YWHAG | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.741); called by muse, varscan2
- ACP1 | c.327C>T p.T109= | Silent (SNP) | VAF 35/223 reads (16%) | catalogued as COSV55242188; called by muse, mutect2, varscan2
- BNC1 | c.2673T>C p.D891= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV61756421; called by muse, mutect2, varscan2
- CSMD1 | c.4374C>A p.G1458= (on ENST00000520002; = p.G1457= on NM_033225.6) | Silent (SNP) | VAF 15/141 reads (11%) | catalogued as COSV59279336; called by muse, mutect2, varscan2
- CYP11B2 | c.1425A>G p.T475= | Silent (SNP) | VAF 90/243 reads (37%) | catalogued as COSV59994357; called by muse, mutect2, varscan2
- DPP6 | c.567C>T p.A189= (on ENST00000377770 / NM_001364500.2; = p.A127= on NM_001936.5) | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as COSV59596810; called by muse, mutect2, varscan2
- EPHA5 | c.948C>T p.I316= | Silent (SNP) | VAF 36/198 reads (18%) | catalogued as COSV56629985; called by muse, mutect2, varscan2
- EPHA7 | c.114T>A p.S38= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV65168541; called by muse, mutect2, varscan2
- FLRT3 | c.783G>A p.R261= | Silent (SNP) | VAF 27/121 reads (22%) | catalogued as COSV53942486; called by muse, mutect2, varscan2
- ITGB8 | c.1932T>A p.L644= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as COSV56004587; called by muse, mutect2, varscan2
- ITSN1 | c.3480G>A p.V1160= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV66080545; called by mutect2, varscan2
- NDST3 | c.1914T>C p.N638= | Silent (SNP) | VAF 43/219 reads (20%) | catalogued as rs778561894, COSV56612758; called by muse, mutect2, varscan2
- NTF3 | c.141G>A p.K47= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs1326532997, COSV100451061, COSV58417133; called by muse, mutect2, varscan2
- OR2B11 | c.894T>C p.N298= | Silent (SNP) | VAF 26/168 reads (15%) | catalogued as COSV59509217; called by muse, mutect2, varscan2
- PCDH11Y | c.1972C>A p.R658= (on ENST00000400457 / NM_032973.2; = p.R647= on NM_032971.3) | Silent (SNP) | VAF 39/186 reads (21%) | catalogued as COSV99290929; called by muse, mutect2, varscan2
- PCDHA6 | c.2373A>G p.L791= | Silent (SNP) | VAF 13/158 reads (8%) | catalogued as COSV65341659; called by muse, mutect2
- PCDHGA6 | c.45G>T p.L15= | Silent (SNP) | VAF 41/154 reads (27%) | catalogued as rs376765941; called by muse, mutect2, varscan2
- PRRT3 | c.222T>C p.D74= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as COSV55976248; called by muse, mutect2, varscan2
- SPATA2 | c.345G>T p.T115= | Silent (SNP) | VAF 24/252 reads (10%) | catalogued as COSV56865332; called by muse, mutect2
- TTC27 | c.351C>T p.H117= | Silent (SNP) | VAF 72/430 reads (17%) | catalogued as rs1305032899, COSV58648594; called by muse, mutect2, varscan2
- ZNF229 | c.276T>C p.D92= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as COSV52159352; called by muse, mutect2
- ABHD11 | c.288+238G>T | Intron (SNP) | VAF 14/62 reads (23%) | catalogued as COSV99766721; called by muse, varscan2
- ABHD11 | c.288+237G>T | Intron (SNP) | VAF 14/62 reads (23%) | catalogued as COSV99766724; called by muse, varscan2
- DCHS2 | n.4047G>T | RNA (SNP) | VAF 45/292 reads (15%) | catalogued as COSV61767713; called by muse, mutect2, varscan2
- IKBIP | c.297+8188T>C | Intron (SNP) | VAF 67/386 reads (17%) | catalogued as COSV54488372; called by muse, mutect2, varscan2
- IL13RA2 | c.*18A>T | 3'UTR (SNP) | VAF 83/300 reads (28%) | catalogued as COSV99682951; called by muse, mutect2, varscan2
- SPRY3 | c.*2642C>T | 3'UTR (SNP) | VAF 61/424 reads (14%) | catalogued as COSV100249245; called by muse, mutect2, varscan2
- SPRY3 | c.*4031G>C | 3'UTR (SNP) | VAF 13/226 reads (6%) | called by muse, mutect2
